Somatic mutation profile of tumor specimen HTMCP-03-06-02412-01A (aliquot HTMCP-03-06-02412-01A-01D-10409) from CGCI case HTMCP-03-06-02412, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 48.0 years (17,528 days).
Specimen HTMCP-03-06-02412-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0db9d44d-2e4e-41b0-9a4c-2a0f27cf066a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02412-10A (Blood Derived Normal), aliquot HTMCP-03-06-02412-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb212be0-7d43-451f-b57c-530a08b33743

The open-access MAF lists 81 somatic variants for this specimen: 54 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 23, Nonsense Mutation 4, Intron 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 45/251 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 52/249 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.1123C>T p.P375S (on ENST00000611781; = p.P319S on NM_052997.2) | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV64603428; called by muse, mutect2, varscan2
- COL3A1 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV58596225; called by muse, mutect2, varscan2
- DGKI | c.2771C>G p.S924C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV55942050; called by muse, mutect2
- DLG1 | c.2051C>T p.S684F (on ENST00000419354 / NM_001290983.1; = p.S706F on NM_004087.2) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs749786841, COSV58393098; called by muse, mutect2, varscan2
- DNAH3 | c.6177C>G p.F2059L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV99771204; called by muse, mutect2, varscan2
- DNAH5 | c.4504C>A p.L1502I | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV99452196; called by muse, mutect2, varscan2
- ENPP2 | c.2539C>A p.P847T (on ENST00000075322 / NM_001040092.3; = p.P899T on NM_006209.5) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV50014644; called by muse, mutect2, varscan2
- FBN1 | c.5743C>T p.R1915C | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1555395826, CM013935; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- FSIP2 | c.20407G>A p.D6803N | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58079469, COSV58096003; called by muse, mutect2, varscan2
- GPRASP2 | c.1218C>G p.I406M | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV100176584; called by muse, mutect2
- HTT | c.7381C>T p.R2461C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764639811, COSV61857079; called by muse, mutect2, varscan2
- IFT122 | c.2018G>A p.R673Q (on ENST00000348417 / NM_052989.3; = p.R614Q on NM_018262.4) | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs140911243, COSV56206008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA2 | c.4849C>T p.Q1617* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV70355335; called by muse, mutect2, varscan2
- LRRCC1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); catalogued as rs761737656; called by muse, mutect2, varscan2
- MGAM | c.5518G>C p.D1840H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs1464994716; called by muse, mutect2
- MLH1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs876659468, COSV51625532; ClinVar: uncertain significance; called by mutect2, varscan2
- MOV10L1 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200913565; called by muse, mutect2, varscan2
- MUC5B | c.10223C>T p.S3408L | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs764862792, COSV71591769; called by muse, varscan2
- MYLK | c.3076G>A p.V1026M | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs778578954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.3026G>C p.G1009A | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55880689; called by muse, mutect2, varscan2
- PLCL1 | c.2761G>T p.A921S | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as COSV70849006; called by muse, mutect2, varscan2
- TLL1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as rs147223461, COSV50322060; called by muse, mutect2, varscan2
- TRIP12 | c.4447C>T p.R1483* | Nonsense Mutation (SNP) | VAF 40/57 reads (70%) | catalogued as COSV52267626; called by muse, mutect2, varscan2
- ZNF274 | c.763G>A p.E255K (on ENST00000610905; = p.E150K on NM_016324.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs929894746, COSV100464713; called by muse, mutect2, varscan2
- ABCC4 | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 110/328 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- AKAP8 | c.1107G>C p.K369N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ARMCX2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BMP10 | c.545A>C p.N182T | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASZ1 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 45/54 reads (83%) | called by muse, mutect2, varscan2
- CCDC168 | c.14575A>T p.N4859Y | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CHD2 | c.2652C>G p.I884M | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DLGAP5 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH11 | c.8849G>A p.G2950E | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- DNM1 | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- FAM71E2 | c.604C>G p.R202G | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNL3L | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KPNA2 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- LIG3 | c.1935G>A p.M645I | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2
- MICAL3 | c.5839G>A p.E1947K | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- MYH7 | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- NACAD | c.4558G>A p.E1520K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- NBPF12 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); called by muse, mutect2
- OCA2 | c.2507G>A p.G836E | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PAPSS2 | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIEZO2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- RGPD8 | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 134/305 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SETD1A | c.3122C>G p.S1041C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SETD2 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- SPTBN1 | c.6304T>A p.S2102T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR3 | c.4567G>A p.E1523K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UBR5 | c.8256C>G p.I2752M | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZFHX3 | c.9307A>G p.N3103D | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATAD5 | c.141G>A p.G47= | Silent (SNP) | VAF 79/141 reads (56%) | called by muse, mutect2, varscan2
- ATP2B2 | c.231G>A p.K77= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as rs1221907020; called by muse, mutect2, varscan2
- BRINP1 | c.2086T>C p.L696= | Silent (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- FAM222B | c.1455C>G p.L485= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs760838516; called by muse, mutect2, varscan2
- FER | c.1057C>T p.L353= | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- FRYL | c.510T>A p.T170= | Silent (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- GREB1 | c.3666G>T p.L1222= | Silent (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- KIF2C | c.1101G>A p.Q367= | Silent (SNP) | VAF 40/155 reads (26%) | called by muse, mutect2, varscan2
- MGAT5B | c.87C>T p.I29= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs538320937; called by muse, mutect2, varscan2
- OBSCN | c.7470C>T p.C2490= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs553927346, COSV52739043; called by muse, varscan2
- PALM3 | c.123C>G p.L41= (on ENST00000340790; = p.L56= on NM_001145028.2) | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- PHKA2 | c.3690G>A p.S1230= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs369001472; called by muse, mutect2, varscan2
- PKLR | c.1041G>A p.E347= | Silent (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- PRDM15 | c.681C>T p.F227= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- PRR32 | c.777C>G p.L259= | Silent (SNP) | VAF 50/486 reads (10%) | called by muse, mutect2
- RALYL | c.693G>A p.Q231= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV72819011; called by muse, mutect2, varscan2
- RXRB | c.621C>T p.I207= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV63399693; called by muse, mutect2, varscan2
- SLC10A3 | c.648G>C p.L216= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- SMG7 | c.786G>C p.L262= | Silent (SNP) | VAF 38/148 reads (26%) | called by muse, mutect2, varscan2
- SYMPK | c.504C>T p.I168= | Silent (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- VPS72 | c.1029G>A p.P343= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs374726504; called by muse, mutect2
- ZMYM4 | c.2475C>T p.L825= | Silent (SNP) | VAF 40/124 reads (32%) | called by muse, varscan2
- ZNF551 | c.543C>T p.F181= | Silent (SNP) | VAF 83/202 reads (41%) | called by muse, mutect2, varscan2
- ELP1 | c.740+9G>C | Intron (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- PTX4 | c.141+362C>T | Intron (SNP) | VAF 16/42 reads (38%) | catalogued as rs1304648205; called by muse, mutect2, varscan2
- RNVU1-27 | n.7A>G | RNA (SNP) | VAF 22/45 reads (49%) | catalogued as rs1362469120; called by muse, mutect2, varscan2
- SLC12A1 | c.*6G>A | 3'UTR (SNP) | VAF 21/42 reads (50%) | catalogued as COSV66799184; called by muse, mutect2, varscan2
